Gene-level copy-number profile of tumor specimen TCGA-FD-A6TI-01A from TCGA case TCGA-FD-A6TI, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 73.6 years (26,874 days).
Specimen TCGA-FD-A6TI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.70ed5932-a7d8-41fa-9255-1c6a5be9db05.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A6TI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4766dc70-33d2-412b-9e6e-cef4fea320c1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 56; copy number 3: 2,594; copy number 4: 32,175; copy number 5: 12,454; copy number 6: 8,149; copy number 7: 1,785; copy number 8: 2,553; copy number 9: 54.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A6TI-01A-11D-A32A-01): tumor purity 0.5, ploidy 4.57, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 54 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:68,591,796–73,092,712, 54 genes, copy number 9 (within-gene range 8–9): LINC01482, AC011591.2, AC011591.1, ABCA8, ABCA9-AS1, ABCA9, ABCA6, SEC24AP1, MIR4524B, MIR4524A, ABCA10, PRO1804, AC005495.1, ABCA5, SNRPGP4, AC115085.1, MAP2K6, AC015920.1, AC002546.1, LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1, AC005771.1, AC007423.1, AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5, AC007432.1, AC005144.1, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9, LINC00511, LINC02003, AC007639.1, RPL32P33, AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
